Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81H, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81H-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: right adrenal

This is a soft tan and necrotic tumor with a diameter of 5 cm with focal areas of more solid, white to gray tissue.

Histologically, this is a pleomorph tumor in part composed of zellballen where single giant cells are present. A capsule is not found. Immunohistochemically, the tumor exhibits a diffuse staining for synaptophysin and chromogranin. Focally, the AE1/3 stains positive. Single sustentacular cells are identified by positive staining for S100. Only the adjacent adrenal parenchyma stains positive for MART1 and inhibin. With Ki67, a proliferation index of 5% is found.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site @ Adrenal gland NOS C74.9
JH 10/17/13

Source: NCI Genomic Data Commons file 132d1e2f-ae4e-4fd0-a58d-fbdbba4efac3 (TCGA-WB-A81H.1BBE4ED0-1371-41F5-912D-B75054C25C48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).